Somatic mutation profile of tumor specimen TCGA-B6-A0RM-01A (aliquot TCGA-B6-A0RM-01A-11D-A099-09) from TCGA case TCGA-B6-A0RM, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage X; Age at diagnosis: 57.6 years (21,047 days).
Specimen TCGA-B6-A0RM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4533d48d-2182-499f-8ebb-43ba75f6d589.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B6-A0RM-10A (Blood Derived Normal), aliquot TCGA-B6-A0RM-10A-01D-A099-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/15924a44-c88b-4287-bf08-3eb0d04f23d0

The open-access MAF lists 30 somatic variants for this specimen: 23 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 16, Silent 7, Frame Shift Del 4, Nonsense Mutation 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FES | c.1873G>T p.V625F | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100183209; called by muse, mutect2, varscan2
- GRIK4 | c.25G>T p.V9L | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101483663; called by muse, mutect2, varscan2
- GSTO2 | c.524A>G p.D175G | Missense Mutation (SNP) | VAF 49/224 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100086793; called by muse, mutect2, varscan2
- IGSF22 | c.1025G>A p.R342H | Missense Mutation (SNP) | VAF 57/268 reads (21%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.998); catalogued as rs201509265; called by muse, mutect2, varscan2
- ITGB4 | c.2220G>A p.K740= | Splice Region (SNP) | VAF 34/83 reads (41%) | catalogued as COSV99564378; called by muse, mutect2, varscan2
- KANSL1 | c.1384C>T p.R462* | Nonsense Mutation (SNP) | VAF 28/93 reads (30%) | catalogued as COSV52267357; called by muse, mutect2, varscan2
- KIF13A | c.4094C>T p.A1365V | Missense Mutation (SNP) | VAF 64/174 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); catalogued as COSV99437001; called by muse, mutect2, varscan2
- LGALS14 | c.31C>T p.P11S | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.68); PolyPhen benign (0.042); catalogued as COSV100648462; called by muse, mutect2, varscan2
- MAP3K1 | c.1573C>T p.Q525* | Nonsense Mutation (SNP) | VAF 48/122 reads (39%) | catalogued as COSV68127752; called by muse, mutect2, varscan2
- MAP3K1 | c.4302T>A p.S1434R | Missense Mutation (SNP) | VAF 101/252 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV101267070; called by muse, mutect2, varscan2
- NASP | c.1682C>T p.A561V | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100601911; called by muse, mutect2, varscan2
- NEK5 | c.869G>A p.R290Q | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs556430126, COSV100839272, COSV62879908; called by muse, mutect2, varscan2
- OR51D1 | c.764T>C p.I255T | Missense Mutation (SNP) | VAF 68/183 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.278); catalogued as COSV100712410; called by muse, mutect2
- PLAAT1 | c.742G>A p.V248I (on ENST00000650797; = p.V143I on NM_020386.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 98/255 reads (38%) | SIFT tolerated (0.86); PolyPhen benign (0.014); catalogued as rs147242865; called by muse, mutect2, varscan2
- SAMD15 | c.710A>G p.K237R | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.288); catalogued as COSV99375104; called by muse, mutect2, varscan2
- SLC35G3 | c.127G>T p.A43S | Missense Mutation (SNP) | VAF 61/152 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.985); catalogued as COSV52012095, COSV99268940; called by muse, mutect2, varscan2
- TBC1D21 | c.991T>A p.L331I | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.629); catalogued as COSV100311454, COSV55996111; called by muse, mutect2, varscan2
- YLPM1 | c.2488C>T p.P830S | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.147); catalogued as COSV99460534; called by muse, mutect2, varscan2
- ZNF585B | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 86/241 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.028); catalogued as COSV100459559; called by muse, mutect2, varscan2
- NAB1 | c.392del p.A131Vfs*20 | Frame Shift Del (DEL) | VAF 25/87 reads (29%) | called by mutect2, pindel, varscan2
- PDPR | c.2461del p.S821Lfs*10 | Frame Shift Del (DEL) | VAF 40/143 reads (28%) | called by mutect2, pindel, varscan2
- PLA2G6 | c.2413del p.S805Hfs*13 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | called by mutect2, pindel
- RTN1 | c.578_591del p.A193Gfs*21 | Frame Shift Del (DEL) | VAF 73/219 reads (33%) | called by mutect2, pindel, varscan2
- FAM71D | c.1044A>G p.Q348= | Silent (SNP) | VAF 42/106 reads (40%) | catalogued as rs746504779, COSV100315298; called by muse, mutect2, varscan2
- INPPL1 | c.1770C>T p.L590= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as rs1309918769, COSV99996437; called by muse, mutect2, varscan2
- KIF2C | c.792G>A p.R264= | Silent (SNP) | VAF 49/100 reads (49%) | catalogued as COSV100945786; called by muse, mutect2, varscan2
- NGF | c.402G>A p.S134= | Silent (SNP) | VAF 31/71 reads (44%) | catalogued as rs565841831, COSV101049610; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC6A20 | c.831C>T p.I277= | Silent (SNP) | VAF 76/199 reads (38%) | catalogued as COSV62071392; called by muse, mutect2, varscan2
- SPTBN5 | c.10773C>T p.L3591= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as COSV100311858; called by muse, mutect2, varscan2
- ST3GAL2 | c.165C>T p.A55= | Silent (SNP) | VAF 16/19 reads (84%) | catalogued as rs762496575, COSV100735633; called by muse, mutect2, varscan2
